Somatic mutation profile of tumor specimen TCGA-HP-A5N0-01A (aliquot TCGA-HP-A5N0-01A-11D-A28X-10) from TCGA case TCGA-HP-A5N0, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, clear cell type; Tissue or organ of origin: Liver; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-HP-A5N0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9beb2758-8ad9-48ac-ac4f-a6326cd48337.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HP-A5N0-10A (Blood Derived Normal), aliquot TCGA-HP-A5N0-10A-01D-A28X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3fd800a-0970-4848-98e4-437de4197736

The open-access MAF lists 143 somatic variants for this specimen: 109 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 31, Frame Shift Del 9, Nonsense Mutation 3, Splice Site 3, RNA 2, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 4/98 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1057519872, COSV55911123; ClinVar: not provided; called by muse, mutect2
- ABCB11 | c.1688A>G p.Q563R | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99792387; called by muse, varscan2
- ACTN3 | c.592C>A p.H198N | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as COSV72207632; called by muse, mutect2, varscan2
- ACVR2A | c.1096A>G p.M366V | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54025388; called by muse, mutect2, varscan2
- ADAM8 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.84); PolyPhen benign (0.079); catalogued as COSV69864922; called by muse, mutect2, varscan2
- ANKRD24 | c.3101C>T p.A1034V | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); catalogued as rs1201577783, COSV53672823; called by muse, mutect2, varscan2
- ANO5 | c.1031C>A p.P344H | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV61087477; called by muse, mutect2, varscan2
- ARRB1 | c.1023-1G>A p.X341_splice | Splice Site (SNP) | VAF 23/77 reads (30%) | catalogued as COSV63576468; called by muse, mutect2, varscan2
- ASPM | c.1828A>G p.K610E | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs769895394, COSV54133308; called by muse, mutect2, varscan2
- ATP10A | c.4204G>T p.V1402F | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.021); catalogued as COSV100791340; called by muse, mutect2, varscan2
- B4GALNT2 | c.1531G>T p.G511W | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1284688144, COSV55925953, COSV55927188; called by muse, mutect2, varscan2
- BPIFC | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as COSV55913707; called by muse, mutect2, varscan2
- BRINP3 | c.925A>C p.T309P | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.348); catalogued as COSV66530800; called by muse, mutect2, varscan2
- CACNG2 | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.287); catalogued as COSV100268858; called by muse, mutect2, varscan2
- CACNG2 | c.233A>T p.K78M | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.796); catalogued as COSV100268859; called by muse, mutect2, varscan2
- CAMSAP2 | c.2653G>T p.E885* (on ENST00000236925 / NM_001297707.2; = p.E874* on NM_203459.3) | Nonsense Mutation (SNP) | VAF 34/146 reads (23%) | catalogued as COSV52669844; called by muse, varscan2
- CASZ1 | c.2329C>T p.P777S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59738271; called by muse, mutect2, varscan2
- CD109 | c.556C>G p.L186V | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.309); catalogued as COSV54652749, COSV99069026; called by muse, mutect2, varscan2
- CD244 | c.887T>C p.I296T (on ENST00000368033 / NM_001166663.2; = p.I291T on NM_016382.4) | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as rs1218239896, COSV59239507; called by muse, mutect2, varscan2
- CEACAM3 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV55762279; called by muse, mutect2, varscan2
- CEP164 | c.4284G>T p.R1428S | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV54043460; called by muse, mutect2, varscan2
- CFAP161 | c.19G>T p.G7C | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV54429830; called by muse, mutect2, varscan2
- CHRNA6 | c.1136C>A p.A379D | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV52378675, COSV52380271; called by muse, mutect2, varscan2
- CLCNKA | c.272T>G p.L91R | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV58892636; called by muse, mutect2, varscan2
- CLEC1B | c.478G>T p.G160* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV53724956, COSV53725984; called by muse, mutect2, varscan2
- COL6A3 | c.3955G>T p.V1319L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as rs866330385, COSV55097539; called by muse, mutect2, varscan2
- DDX6 | c.1007A>T p.Q336L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50590057; called by muse, mutect2, varscan2
- DEGS1 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1405720523, COSV60379647; called by muse, mutect2, varscan2
- DNAH9 | c.4658T>G p.L1553R | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52359905; called by muse, mutect2, varscan2
- DOK3 | c.-118+1G>A | Splice Site (SNP) | VAF 26/113 reads (23%) | catalogued as COSV57253228; called by muse, mutect2, varscan2
- ESCO2 | c.1119C>G p.D373E | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV59415425; called by muse, mutect2, varscan2
- EXOSC5 | c.617T>C p.L206P | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV55371550; called by muse, mutect2
- EXTL1 | c.857T>C p.F286S | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV65337089, COSV65337929; called by muse, mutect2, varscan2
- FAM122B | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV53231830; called by muse, mutect2, varscan2
- FAM171A1 | c.193T>C p.S65P | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV65317518; called by muse, mutect2, varscan2
- FAM47A | c.489G>T p.W163C | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV60498197; called by muse, mutect2
- FLNC | c.2159C>T p.P720L | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV100368368, COSV57959448; called by muse, mutect2
- FNBP1 | c.581T>C p.L194P | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63088726; called by muse, mutect2, varscan2
- FRMPD1 | c.4702T>G p.L1568V | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66701179; called by muse, mutect2, varscan2
- GALNTL6 | c.1532C>G p.P511R | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV72491987; called by muse, mutect2, varscan2
- GPR34 | c.931A>T p.I311F | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59370760; called by muse, mutect2, varscan2
- GRM7 | c.1355T>C p.I452T | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV63153049; called by muse, mutect2, varscan2
- GYS1 | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as COSV54403901; called by muse, mutect2, varscan2
- HECW2 | c.682G>T p.G228W | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53665607; called by muse, mutect2, varscan2
- HNRNPH1 | c.294G>T p.K98N | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV61487215; called by muse, mutect2, varscan2
- HOXA6 | c.410A>T p.Y137F | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV56074048; called by muse, mutect2, varscan2
- KCNA2 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1271481592, COSV60370794; called by muse, mutect2, varscan2
- KIAA1217 | c.4675G>T p.E1559* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100286792; called by mutect2, varscan2
- KIF25 | c.845C>G p.T282S | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.241); catalogued as COSV63027971; called by muse, mutect2, varscan2
- KLK11 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.355); catalogued as COSV51577868; called by muse, mutect2, varscan2
- KRTAP1-1 | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.23); catalogued as COSV60398702; called by muse, mutect2, varscan2
- LILRA4 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as COSV52493325; called by muse, mutect2, varscan2
- LMBRD2 | c.787C>A p.P263T | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.652); catalogued as COSV56951171; called by muse, mutect2, varscan2
- LMTK2 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs531778656, COSV51999337; called by muse, mutect2, varscan2
- LRRIQ1 | c.2321C>A p.P774Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV67833999; called by muse, mutect2, varscan2
- LRWD1 | c.719T>G p.L240R | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.259); catalogued as COSV52961377; called by muse, mutect2, varscan2
- MTO1 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs868497455, COSV64774256; called by muse, mutect2
- MUC5B | c.8653T>A p.Y2885N | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV101500439; called by muse, mutect2, varscan2
- MXRA5 | c.5303C>G p.S1768C | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV54241660, COSV99479847; called by muse, mutect2, varscan2
- MYH15 | c.4198G>C p.D1400H | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV56314247; called by muse, mutect2, varscan2
- NCOA6 | c.1256A>T p.Q419L | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.777); catalogued as COSV62865521; called by muse, mutect2, varscan2
- NLRP13 | c.2560G>T p.G854C | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV61622885, COSV61624161; called by muse, mutect2, varscan2
- NLRP9 | c.1992C>T p.L664= | Splice Region (SNP) | VAF 18/66 reads (27%) | catalogued as COSV60465323; called by muse, mutect2, varscan2
- NOD2 | c.2581C>T p.H861Y | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56052730; called by muse, mutect2, varscan2
- NWD1 | c.4279A>G p.S1427G | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as COSV60346007; called by muse, mutect2, varscan2
- OR2A14 | c.675G>T p.L225F | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68718402; called by muse, mutect2, varscan2
- OR2T2 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100737698; called by muse, mutect2, varscan2
- OR52D1 | c.361A>T p.M121L | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV59487897; called by muse, mutect2, varscan2
- PHF8 | c.2414C>T p.P805L (on ENST00000357988 / NM_001184896.1; = p.P769L on NM_015107.3) | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs1557099111, COSV57678080, COSV57684195; called by mutect2, varscan2
- PIK3CG | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs760224981, COSV63250351; called by mutect2, varscan2
- PKHD1L1 | c.12665G>T p.R4222I | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); catalogued as COSV65747182; called by muse, mutect2, varscan2
- PLK4 | c.2694G>T p.W898C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV54638376, COSV99584531; called by muse, mutect2, varscan2
- PODNL1 | c.1498_1501del p.N500Ffs*2 | Frame Shift Del (DEL) | VAF 22/117 reads (19%) | catalogued as rs1314367028; called by mutect2, pindel, varscan2
- PSG11 | c.599G>T p.R200M | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60456403; called by muse, mutect2, varscan2
- PTCHD1 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV65061561; called by muse, mutect2, varscan2
- RAPGEF2 | c.1501T>C p.S501P | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1235889807, COSV52430592; called by muse, mutect2, varscan2
- RNF213 | c.7561A>G p.I2521V | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as rs1425008837, COSV60402490; called by muse, mutect2, varscan2
- RXFP3 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.177); catalogued as COSV100347605; called by muse, mutect2
- RXYLT1 | c.291T>A p.D97E | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV54169095; called by muse, mutect2, varscan2
- SIDT2 | c.907A>G p.I303V | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as COSV54054876; called by muse, mutect2, varscan2
- SLC16A14 | c.377T>G p.L126R | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV54619609; called by muse, mutect2, varscan2
- SLC28A3 | c.1105T>C p.S369P | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV66154030; called by muse, mutect2, varscan2
- SLC34A2 | c.683T>A p.V228E | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65942193; called by muse, mutect2, varscan2
- SLC36A4 | c.155A>G p.Q52R | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV58396892; called by muse, mutect2, varscan2
- SOS2 | c.541A>T p.I181L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs776470985, COSV53570032; called by muse, mutect2, varscan2
- SPAG16 | c.1817C>A p.A606E | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV56974277; called by muse, mutect2, varscan2
- SPTB | c.1913G>C p.R638P | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV67632546, COSV67633294; called by muse, mutect2, varscan2
- TAS2R41 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV68765569, COSV68765646; called by muse, mutect2, varscan2
- TMEM71 | c.680C>A p.T227N (on ENST00000523829 / NM_001382398.1; = p.T208N on NM_144649.3) | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV63458189; called by muse, varscan2
- TMPRSS11D | c.113T>A p.V38D | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV52224514; called by muse, mutect2
- TNR | c.3779A>G p.Y1260C | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1449296576, COSV54883225; called by muse, mutect2, varscan2
- TRIM37 | c.2500G>T p.D834Y | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV51886013; called by muse, varscan2
- TRPA1 | c.656G>A p.R219K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1002728997, COSV51566709; called by muse, mutect2, varscan2
- TRPM6 | c.5516A>T p.K1839I | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62515570; called by muse, mutect2
- TTC13 | c.1717A>G p.R573G | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV64169054; called by muse, mutect2, varscan2
- UBXN10 | c.763A>C p.T255P | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV66772363; called by muse, mutect2, varscan2
- UCP1 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53768108; called by muse, mutect2, varscan2
- VGLL2 | c.289T>C p.S97P | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV100409944; called by muse, mutect2
- ZMAT4 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52703796; called by muse, mutect2, varscan2
- ZNF286A | c.953G>T p.R318I | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.095); catalogued as rs1421497314, COSV67845940; called by muse, mutect2, varscan2
- DCAF6 | c.750del p.N250Kfs*7 | Frame Shift Del (DEL) | VAF 32/147 reads (22%) | called by mutect2, pindel, varscan2
- GIPR | c.882_895delinsTTG p.I295Cfs*12 | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | called by pindel, varscan2*
- GPRASP2 | c.380_390del p.Q127Pfs*3 | Frame Shift Del (DEL) | VAF 36/120 reads (30%) | called by mutect2, pindel, varscan2
- JMY | c.1032+3_1032+18del p.X344_splice | Splice Site (DEL) | VAF 15/101 reads (15%) | called by mutect2, pindel, varscan2
- KCNIP1 | c.189del p.E63Dfs*55 (on ENST00000411494 / NM_001034837.3; = p.E52Dfs*55 on NM_014592.4) | Frame Shift Del (DEL) | VAF 21/72 reads (29%) | called by mutect2, varscan2
- KMT2A | c.4914del p.E1639Sfs*6 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | called by mutect2, pindel
- MEGF8 | c.4000del p.T1334Pfs*5 (on ENST00000251268 / NM_001271938.2; = p.T1267Pfs*5 on NM_001410.3) | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- RYR1 | c.6612_6661del p.H2204Qfs*32 | Frame Shift Del (DEL) | VAF 28/125 reads (22%) | called by mutect2, pindel
- ZNF195 | c.711_718del p.S237Rfs*22 (on ENST00000399602 / NM_001130520.3; = p.S165Rfs*22 on NM_007152.5) | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- AIFM1 | c.1680C>T p.Y560= | Silent (SNP) | VAF 29/226 reads (13%) | catalogued as rs776215622, COSV54855938; called by muse, mutect2, varscan2
- ATP10A | c.4203T>G p.A1401= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100791342; called by muse, mutect2, varscan2
- ATP10B | c.324C>T p.P108= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as COSV58779649; called by muse, mutect2, varscan2
- BHLHE23 | c.615C>T p.D205= (on ENST00000370346; = p.D221= on NM_080606.4) | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV64846530; called by muse, mutect2, varscan2
- CRY1 | c.528A>G p.E176= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV50485753; called by muse, varscan2
- CSPG5 | c.870A>G p.G290= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV53132123; called by muse, mutect2, varscan2
- DNAH1 | c.4455G>A p.Q1485= | Silent (SNP) | VAF 64/165 reads (39%) | catalogued as COSV70231849; called by muse, mutect2, varscan2
- DNAH9 | c.3906G>A p.L1302= | Silent (SNP) | VAF 54/135 reads (40%) | catalogued as rs1249589880, COSV52359888; called by muse, mutect2, varscan2
- EDEM3 | c.489C>A p.I163= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV58925953; called by muse, mutect2, varscan2
- FMC1-LUC7L2 | c.9C>T p.A3= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs530614678, COSV52546081; called by muse, mutect2, varscan2
- GPR31 | c.219C>T p.F73= | Silent (SNP) | VAF 44/160 reads (28%) | catalogued as rs1260800078, COSV64761762; called by muse, mutect2, varscan2
- GZMM | c.762C>G p.G254= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV52742564; called by muse, mutect2, varscan2
- HSPA14 | c.252C>T p.I84= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs375004850, COSV65684649; called by muse, mutect2, varscan2
- HTT | c.8706G>T p.L2902= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV61865181; called by muse, mutect2, varscan2
- KRT85 | c.261G>A p.V87= | Silent (SNP) | VAF 64/321 reads (20%) | catalogued as COSV57737438; called by muse, mutect2, varscan2
- NEB | c.4188C>A p.A1396= | Silent (SNP) | VAF 84/191 reads (44%) | catalogued as COSV51433686; called by muse, mutect2, varscan2
- OR10Z1 | c.6G>T p.G2= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as COSV63525581; called by muse, mutect2, varscan2
- PAPPA | c.1176C>G p.S392= | Silent (SNP) | VAF 42/145 reads (29%) | catalogued as COSV60287377; called by muse, mutect2, varscan2
- PPRC1 | c.4932C>T p.S1644= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV53386896; called by muse, mutect2, varscan2
- PRF1 | c.1509T>C p.S503= | Silent (SNP) | VAF 41/77 reads (53%) | catalogued as COSV64615390; called by muse, mutect2, varscan2
- RELN | c.6993T>C p.D2331= | Silent (SNP) | VAF 39/115 reads (34%) | catalogued as COSV59016287; called by muse, mutect2, varscan2
- ROS1 | c.6111T>C p.Y2037= | Silent (SNP) | VAF 6/126 reads (5%) | catalogued as COSV63857704; called by muse, mutect2
- SAFB2 | c.213T>C p.P71= | Silent (SNP) | VAF 5/96 reads (5%) | catalogued as COSV52652481; called by muse, mutect2
- SALL2 | c.1512A>T p.G504= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV58104429; called by muse, mutect2, varscan2
- SHROOM2 | c.201G>A p.K67= | Silent (SNP) | VAF 53/179 reads (30%) | catalogued as rs879221119, COSV66608456; called by muse, varscan2
- SLIT3 | c.855G>T p.T285= | Silent (SNP) | VAF 47/199 reads (24%) | catalogued as COSV60619675; called by muse, mutect2, varscan2
- TMEM145 | c.1338G>C p.T446= | Silent (SNP) | VAF 25/176 reads (14%) | catalogued as COSV52092181; called by muse, mutect2, varscan2
- TNKS2 | c.177C>T p.S59= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV65416072; called by muse, mutect2, varscan2
- TRIM73 | c.138C>T p.H46= | Silent (SNP) | VAF 28/150 reads (19%) | called by mutect2, varscan2
- VIPR2 | c.402C>T p.Y134= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs547418694, COSV51110489; called by muse, mutect2, varscan2
- ZNF250 | c.1344G>A p.E448= | Silent (SNP) | VAF 50/158 reads (32%) | catalogued as rs1406891998, COSV52969878; called by muse, mutect2, varscan2
- DCHS2 | n.5682T>A | RNA (SNP) | VAF 31/80 reads (39%) | catalogued as COSV61775192; called by muse, mutect2, varscan2
- MCF2 | chrX:139646829 C>A | 5'Flank (SNP) | VAF 98/541 reads (18%) | catalogued as rs773466407, COSV58489117; called by muse, mutect2, varscan2
- MIR372 | n.53A>C | RNA (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
